Surgical pathology report (de-identified scan), TCGA case TCGA-28-5213, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Cedars Sinai, specimen TCGA-28-5213-01A (Primary Tumor).

[page 1 of 5]
Patient: [REDACTED]

Accession Number: [REDACTED]

Hospital No: [REDACTED]

Pathologist: [REDACTED]

Ordering M.D.: [REDACTED]

Date of Birth: [REDACTED]

Assistant: [REDACTED]

Age/Sex: [REDACTED]

Date of Procedure: [REDACTED]

Copies To: [REDACTED]

Date Received: [REDACTED]

Location: [REDACTED]

TCGA-28-5213

SURGICAL PATHOLOGY REPORT

***** Addendum - Please See End of Report *****

Reason for Addendum #1: Additional studies/stains/opinion(s)

DIAGNOSIS:

A. BRAIN, RIGHT TEMPORAL, BIOPSY:

- Glioblastoma multiforme, WHO grade IV, see microscopic

B. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #1:

- Glioblastoma multiforme, WHO grade IV ✓
- 20% of tumor necrosis
- 80% of tumor cellularity

C. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #2:

- Glioblastoma multiforme, WHO grade IV
- 20% of tumor necrosis
- 70% of tumor cellularity

D. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #3:

- Glioblastoma multiforme, WHO grade IV
- 10% of tumor necrosis
- 50% of tumor cellularity

E. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #4:

- Glioblastoma multiforme, WHO grade IV
- 10% of tumor necrosis
- 80% of tumor cellularity

F. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #5:

- Glioblastoma multiforme, WHO grade IV
- 50% of tumor necrosis
- 50% of tumor cellularity

G. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #6:

- Glioblastoma multiforme, WHO grade IV ✓
- 0% of tumor necrosis
- 60% of tumor cellularity

H. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY, NCI #7:

- Glioblastoma multiforme, WHO grade IV
- 5% of tumor necrosis
- 90% of tumor cellularity

I. BRAIN, RIGHT TEMPORAL, CLINICAL TRIAL:

- Glioblastoma multiforme, WHO grade IV

Patient Case(s): [REDACTED]

Copy For: [REDACTED]

Page 1 of 5

PATIENT NOTIFIED OF RESULTS		
DR:	NURSE:	DATE:

[page 2 of 5]
PATIENT:

***** Addendum ***** Please See End of Report *****

ACCESSION #:

J, K. BRAIN, RIGHT TEMPORAL, EXCISIONAL BIOPSY:

- Glioblastoma multiforme, WHO grade IV

COMMENT:

A high percentage of tumor cells (greater than 20%) immunostaining for MGMT has been reported to be associated with a relatively diminished response to [REDACTED]. Hence, the 90% result in this case suggests the possibility of a relatively diminished response to [REDACTED].

Recent studies have shown that co-expression of EGFRvIII and PTEN as detected by immunostaining was significantly correlated with a clinical response of glioblastomas to EGFR kinase inhibitors [REDACTED]. Hence the preserved expression of PTEN in this case, when combined with EGFRvIII mutation, permits a possibility of this tumor being responsive to EGFR-kinase inhibitors.

Retained expression of PTEN was found to be associated with a more favorable prognosis in patients with high grade gliomas [REDACTED].

subclasses of high-grade glioma predict prognosis, delineate a pattern of disease progression, and resemble stages in neurogenesis. Cancer Cell. [REDACTED]

Recent studies indicated an adverse prognostic significance of increased expression of laminin beta 1 and decreased expression of laminin beta 2 predicting a worse survival of patients with gliomas.

[REDACTED] Association between laminin-8 and glial tumor grade, recurrence, and patient survival.

Accordingly, elevated expression of beta 1 and suppressed expression of beta 2 in this tumor predict more aggressive behavior.

Presence of activated (phosphorylated) p42/44 Mitogen-Activated Protein Kinase (pMAPK) often is indicative of an upregulation of receptor tyrosine kinase signaling. It has been shown to be associated with a relative resistance to radiation therapy in glioblastoma multiforme [REDACTED].

Correspondingly, a high percentage of tumor cells immunoreactive to pMAPK antibody in this case may predict a relative resistance to radiation therapy.

The use of these tests in guiding therapy has limitations. Review of the relevant literature and clinical correlation is advised. These test results do not obligate or preclude use of the relevant therapeutic agents.

HISTORY:

Tumor ✓

MICROSCOPIC FINDINGS:

This glioblastoma shows both gemistocytic element as well as perivascular arrangement of cells reminiscent of ependymal differentiation. However, infiltrating component predominates. The tumor associated with degenerating polymorphonuclear leukocytes, resembling abscess formation.

IMMUNOHISTOCHEMISTRY:

Study / Antibody	Block	Result
P53	K7	Up to 1% (3+)
MGMT	K7	Up to 90%
PTEN	K7	Retained (1-2+)
pMAPK	K7	Up to 40% of nuclei and 60% of cytoplasm is positive
Laminin beta 1 (8/411)	K7	Up-regulated (3+)

[page 3 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

Laminin beta 2 (9/421)	K7	Focally down-regulated (1+)
EGFR by FISH	K7	Pending

GROSS:

A. RIGHT TEMPORAL TUMOR

Labeled with the patient's name, labeled "right temporal tumor", and received fresh in the Operating Room for intraoperative frozen consultation and subsequently fixed in formalin is a 0.4 x 0.3 x 0.2 cm portion of tan-brown soft tissue. Portion of this tissue submitted for frozen section diagnosis. Entirely submitted.

A1. Frozen section control for FS#1 (specimen A) - 1

A2. Tissue not utilized for frozen section - 1

B. R TEMPORAL NCI #1

Labeled with the patient's name, labeled "R temporal NCI #1", and received fresh in the Operating Room for tissue procurement and is a 1.5 x 1.0 x 0.5 cm portion of tan-yellow soft tissue. Specimen is entirely submitted for NCI research.

C. R TEMPORAL NCI #2

Labeled with the patient's name, labeled "NCI #2", and received fresh in the Operating Room for tissue procurement and is a 0.9 x 0.7 x 0.4 cm portion of tan-brown tissue. Specimen is entirely submitted for NCI research.

D. R TEMPORAL NCI #3

Labeled with the patient's name, labeled "R temporal NCI #3", and received fresh for tissue procurement and are two portions of tan-brown soft tissue measuring 0.7 and 0.8 cm, respectively, in greatest dimension. Tissue is entirely submitted for NCI study.

E. R TEMPORAL NCI #4

Labeled with the patient's name, labeled "R temporal NCI #4", and received fresh in the Operating Room for tissue procurement and is subsequently fixed in formalin and is a 1.0 x 0.5 x 0.4 cm portion of tan-brown tissue. Specimen is entirely submitted for NCI research.

F. R TEMPORAL NCI #5

Labeled with the patient's name, labeled "R temporal NCI #5", and received in formalin is a 1.2 x 1.2 x 0.5 cm portion of tan-white to tan-brown soft tissue. Specimen is entirely submitted for NCI research.

G. R TEMPORAL NCI #6

Labeled with the patient's name, labeled "R temporal NCI #6", and received fresh in the Operating Room for tissue procurement and is subsequently fixed in formalin and is a 1.0 x 0.8 x 0.4 cm portion of tan-brown focally hemorrhagic soft tissue. Specimen is entirely submitted for NCI research.

H. R TEMPORAL NCI #7

Labeled with the patient's name, labeled "R temporal NCI #7", and received in formalin is a 2.0 x 1.0 x 0.5 cm portion of tan-brown to yellow soft tissue. Specimen is entirely submitted for NCI research.

I. R TEMPORAL CLINICAL TRIAL

Labeled with the patient's name, labeled "R temporal clinical trial", and received in formalin is a 1.5 x 1.0 x 0.5 cm portion of tan-brown to yellow somewhat friable focally necrotic soft tissue. The specimen is entirely submitted.

I1. 4

J. R TEMPORAL PERMANENT

[page 4 of 5]
***** Addendum - Please See End of Report *****

PATIENT: [REDACTED]

ACCESSION #: [REDACTED]

Labeled with the patient's name, labeled "R temporal permanent", and received in formalin are multiple fragmented pieces of tan-brown to yellow somewhat edematous focally necrotic soft friable tissue.

Entirely submitted.

J1-J3. Multiple each

K. BRAIN TUMOR RIGHT TEMPORAL

Labeled with the patient's name, labeled "brain tumor right temporal", and received in formalin are five lobulated portions of brain tissue ranging in size from 2.5 up to 5.5 cm in greatest dimension.

The external surface has distinct gyral folds with majority of the tissue representing soft friable tumor with areas of necrosis.

Representative sections are submitted.

K1-K10. 2 each

Gross dictated by [REDACTED]

INTRAOPERATIVE CONSULTATION:

OPERATIVE CALL

OPERATIVE CONSULT (FROZEN):

R TEMPORAL FS AND TP

- Gemistocytic astrocytoma

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

[page 5 of 5]
PATIENT: [REDACTED]

***** Addendum Please See End of Report *****
ACCESSION #: [REDACTED]

FLUORESCENCE IN SITU HYBRIDIZATION (FISH) for EGFR in BRAIN

Tissue Block: K7

RESULTS: NORMAL EGFR & chromosome 7 signal pattern

Number of cells evaluated: 40

INTERPRETATION:

Fluorescence in situ hybridization (FISH) analysis on a brain tumor sample from this patient with Abbott Molecular probes specific for the centromere of chromosome 7 (control probe) and the short arm (EGFR-7p12) of chromosome 7 was performed. The control sample gave expected results.

These studies did not detect any aberrant signal patterns of EGFR in the 40 nuclei examined, with an EGFR gene to Cep 7 signal ratio of 1.0.

NOTE:

1. Samples are considered positive in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $\geq 10\%$ of analyzed cells or tumors with four or more copies of the EGFR gene in $\geq 40\%$ of the cells (high polysomy).
2. Samples are considered inconclusive, requiring consult with the pathologist, in brain if the EGFR to CEP 7 signal ratio is ≥ 2.0 in $<10\%$ of analyzed cells or when four or more copies of the EGFR gene in $<40\%$ of the cells.

References:

[REDACTED]
These FISH tests were developed and their performance characteristics determined by [REDACTED] as required by the CLIA [REDACTED] regulations. They have not been cleared or approved for specific uses by the U.S. Food and Drug Administration.

I have personally examined the specimen, interpreted the results, reviewed the report and signed it electronically.

SURGICAL PATHOLOGY REPORT

If this report includes immunohistochemical test results, please note the following: Numerous immunohistochemical tests were developed and their performance characteristics determined by [REDACTED]. Those immunohistochemical tests have not been cleared or approved by the U.S. Food and Drug Administration (FDA), and FDA approval is not required.

Source: NCI Genomic Data Commons file 80d5c78d-c539-4143-bd73-ab26d0f008fe (TCGA-28-5213.591247BE-CA98-4187-8280-42B2520E93F7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).